TCGA case TCGA-3A-A9IN — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dd5074b2-462d-4267-8b9b-5a4c54e5978c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/3; ICD-10 code: C25.1; Tissue or organ of origin: Body of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 62.4 years (22,799 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 2,084 days (5.7 years); Sites of involvement: Pancreas Body; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Tumor largest dimension diameter: 5 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Days to treatment start: 193 days; Days to treatment end: 231 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 193 days; Days to treatment end: 231 days; Treatment dose: 5,040 cGy; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS.

Follow-up (1 entry)
- Days to follow up: 2,084 days (5.7 years); Disease response: Tumor Free.

Exposures
- Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Alcohol drinks per day: 1; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3A-A9IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-3A-A9IN-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3A-A9IN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3A-A9IN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma-Other Subtype; Histologic diagnosis other: Neuroendocrine carcinoma nos; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tissue Biopsy; Surgical procedure: Other Method (please specify); Lymph nodes examined: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Alcohol exposure intensity: Daily Drinker; Alcohol consumption frequency: 7; Diabetes diagnosis indicator: No; History chronic pancreatitis: No; Surgical procedure other: Subtotal pancreatectomy; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Item does not meet study protocol: This case is a neuroendocrine tumor and should not have been included in the PAAD study.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,084 days; disease-specific survival: no event (censored), 2,084 days; disease-free interval: no event (censored), 2,084 days; progression-free interval: no event (censored), 2,084 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3A-A9IN-01A-11D-A396-01): tumor purity 0.69, ploidy 1.41, whole-genome doublings 0.
